Somatic mutation profile of tumor specimen TCGA-BT-A20V-01A (aliquot TCGA-BT-A20V-01A-11D-A14W-08) from TCGA case TCGA-BT-A20V, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 59.0 years (21,551 days).
Specimen TCGA-BT-A20V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93635fd2-1390-4e67-9fc0-f654f769bb4a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BT-A20V-11A (Solid Tissue Normal), aliquot TCGA-BT-A20V-11A-11D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/62987ae6-687f-4b06-a29d-322451aed3fe

The open-access MAF lists 107 somatic variants for this specimen: 80 protein-altering or splice-affecting, 24 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 24, Nonsense Mutation 6, In Frame Ins 2, Splice Site 1, Intron 1, Frame Shift Del 1, In Frame Del 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC023055.1 | c.1207G>A p.V403M | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV60243488; called by muse, mutect2, varscan2
- ANK1 | c.1438A>G p.I480V | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs544269725, COSV55883715; called by muse, mutect2, varscan2
- ARMCX1 | c.28G>A p.V10M | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.907); catalogued as COSV65705267; called by muse, mutect2, varscan2
- ASCC3 | c.1274T>C p.I425T | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV100225865, COSV61229386; called by muse, mutect2
- ATRX | c.7048C>G p.L2350V | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV64877902; called by muse, mutect2, varscan2
- BCLAF1 | c.2050A>G p.K684E | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.859); catalogued as COSV50357929; called by muse, mutect2, varscan2
- BOC | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs142142926; called by muse, mutect2, varscan2
- BRINP3 | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV66522433; called by muse, mutect2, varscan2
- C2CD5 | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV61725070; called by muse, mutect2, varscan2
- CD164L2 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs766830631, COSV64995748; called by muse, mutect2, varscan2
- CD1D | c.815G>T p.G272V | Missense Mutation (SNP) | VAF 53/94 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.321); catalogued as COSV63809165; called by muse, mutect2, varscan2
- CDH11 | c.1795G>A p.G599R | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV51764630; called by muse, mutect2, varscan2
- CDH9 | c.1481C>T p.T494I | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.58); catalogued as COSV50298394; called by muse, mutect2, varscan2
- CHPT1 | c.552G>C p.L184F | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57533728; called by muse, mutect2, varscan2
- CREB3L3 | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as rs377239800; called by muse, mutect2, varscan2
- CRIM1 | c.2886G>C p.Q962H | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as rs13419463; called by muse, mutect2, varscan2
- DGKE | c.307G>C p.D103H | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as COSV52350001, COSV52350587; called by muse, varscan2
- DNAH1 | c.2554C>T p.R852C | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs546135785, COSV70229937; called by muse, mutect2, varscan2
- EFTUD2 | c.2869A>G p.M957V | Missense Mutation (SNP) | VAF 105/165 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as COSV53655056; called by muse, mutect2, varscan2
- ELP1 | c.515G>A p.G172E | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65898129; called by muse, mutect2, varscan2
- FLRT1 | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs756527574, COSV55358906; ClinVar: uncertain significance; called by muse, mutect2
- GAREM1 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV52510687; called by muse, mutect2, varscan2
- GOLGB1 | c.2192A>T p.N731I | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as COSV61466595; called by muse, mutect2, varscan2
- GPR108 | c.1564A>C p.T522P (on ENST00000264080 / NM_001080452.1; = p.T280P on NM_020171.2) | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV51185066, COSV51185091; called by muse, mutect2, varscan2
- HCN1 | c.2644G>A p.E882K | Missense Mutation (SNP) | VAF 32/352 reads (9%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.014); catalogued as COSV57515403; called by muse, mutect2
- HMCN1 | c.10312A>T p.N3438Y | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); catalogued as COSV54906880; called by muse, varscan2
- HTATIP2 | c.193G>T p.V65L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as COSV70041279; called by muse, mutect2, varscan2
- IL34 | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs773778670, COSV55380003; called by mutect2, varscan2
- KCNF1 | c.1250G>A p.R417H | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.379); catalogued as COSV54462706; called by muse, mutect2, varscan2
- KCTD15 | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1342751760, COSV52290455; called by muse, mutect2, varscan2
- KIAA1841 | c.1057C>T p.R353* | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | catalogued as rs1430130819; called by muse, mutect2, varscan2
- KIF6 | c.1111C>A p.L371M | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54680579; called by muse, mutect2, varscan2
- L3MBTL4 | c.769C>G p.L257V | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53125260; called by muse, mutect2, varscan2
- LCT | c.5308C>T p.R1770W | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1257485651, COSV51550976; called by muse, mutect2, varscan2
- MAN2B1 | c.2123G>A p.R708Q | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.86); catalogued as rs371812948; called by muse, mutect2, varscan2
- MCHR1 | c.865C>A p.P289T | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs994447443, COSV50761367; called by muse, mutect2, varscan2
- MYOCD | c.2563G>A p.E855K | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as COSV58504990; called by muse, mutect2, varscan2
- NOTCH1 | c.778G>T p.D260Y | Missense Mutation (SNP) | VAF 98/232 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53057735; called by muse, mutect2, varscan2
- OR6M1 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs758825682, COSV58433139, COSV58433836; called by muse, mutect2, varscan2
- OR8K1 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.164); catalogued as COSV54402839; called by muse, mutect2, varscan2
- PCDHA7 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 60/276 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.011); catalogued as COSV65344678; called by muse, mutect2, varscan2
- PPFIBP2 | c.982C>T p.L328F | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as COSV55078072; called by muse, mutect2, varscan2
- PYGO2 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.208); catalogued as COSV63757109; called by muse, mutect2, varscan2
- RBBP6 | c.2573A>G p.E858G | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.537); catalogued as COSV60503290, COSV60505713; called by muse, mutect2, varscan2
- RBM10 | c.1795A>C p.N599H | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV61309642; called by muse, mutect2, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 18/38 reads (47%) | catalogued as rs762006287; called by mutect2, varscan2
- RC3H1 | c.1215G>T p.Q405H | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.758); catalogued as COSV51202414; called by muse, mutect2, varscan2
- RERGL | c.582C>G p.I194M | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.994); catalogued as rs751389138, COSV57461184, COSV57463675; called by muse, mutect2
- RXRG | c.971G>T p.G324V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100717205, COSV63232286; called by muse, mutect2, varscan2
- SCAF11 | c.3388G>C p.E1130Q | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); catalogued as COSV65476978; called by muse, mutect2, varscan2
- SCAF11 | c.256C>G p.Q86E | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.55); catalogued as COSV56977780; called by muse, mutect2, varscan2
- SLC20A1 | c.727G>T p.A243S | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as rs774549910, COSV55611574, COSV55613389; called by muse, mutect2, varscan2
- SMOX | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs145030123, COSV53865591; called by muse, mutect2, varscan2
- SNRPB | c.197T>G p.V66G | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV60015730; called by muse, mutect2, varscan2
- SPECC1L | c.750T>A p.N250K | Missense Mutation (SNP) | VAF 43/189 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58659021; called by muse, mutect2, varscan2
- SPESP1 | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52989803; called by muse, mutect2, varscan2
- STK38 | c.386A>G p.E129G | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.72); catalogued as COSV57709179; called by muse, mutect2, varscan2
- TAGLN3 | c.366G>A p.M122I | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.116); catalogued as rs1232390305, COSV56327481, COSV56328111; called by muse, mutect2
- TASP1 | c.84A>T p.K28N | Missense Mutation (SNP) | VAF 38/494 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.092); catalogued as COSV61813442; called by muse, mutect2
- TKTL1 | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV54212319; called by muse, mutect2, varscan2
- TMEM184A | c.192G>A p.W64* | Nonsense Mutation (SNP) | VAF 16/42 reads (38%) | catalogued as rs762397202; called by muse, mutect2, varscan2
- TNN | c.2563C>A p.L855M | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV53427907; called by muse, mutect2, varscan2
- TRIM41 | c.1795G>A p.A599T | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as rs778188838, COSV59319658; called by muse, mutect2, varscan2
- UBN2 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746848105, COSV56031400, COSV99944221; called by muse, mutect2, varscan2
- ULK1 | c.2999G>A p.R1000H | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as rs749327954, COSV58857331; called by muse, mutect2, varscan2
- WDR72 | c.2428G>T p.D810Y | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV64748144; called by muse, mutect2, varscan2
- ZNF205 | c.1084A>G p.K362E | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV54621381; called by muse, mutect2, varscan2
- ZNF275 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.56); catalogued as COSV64704675; called by muse, mutect2, varscan2
- ZNF404 | c.366G>C p.K122N | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV60987624; called by muse, mutect2, varscan2
- ZNF99 | c.1646C>A p.S549Y | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.236); catalogued as COSV68055922, COSV68056713; called by muse, mutect2, varscan2
- ACAD11 | c.451G>T p.E151* | Nonsense Mutation (SNP) | VAF 23/129 reads (18%) | called by muse, mutect2, varscan2
- ANKRD30A | c.1624A>T p.N542Y (on ENST00000611781; = p.N486Y on NM_052997.2) | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- EFCAB6 | c.952T>G p.S318A | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.684); called by muse, mutect2
- ELAPOR1 | c.1961_1963dup p.C654dup | In Frame Ins (INS) | VAF 15/69 reads (22%) | called by mutect2, pindel, varscan2
- GPBP1L1 | c.191-6_191-2del p.X64_splice | Splice Site (DEL) | VAF 8/25 reads (32%) | called by mutect2, varscan2
- MYO3A | c.4702C>T p.Q1568* | Nonsense Mutation (SNP) | VAF 16/77 reads (21%) | called by muse, mutect2, varscan2
- NISCH | c.106C>T p.Q36* | Nonsense Mutation (SNP) | VAF 67/205 reads (33%) | called by muse, mutect2, varscan2
- PLXNB3 | c.1621C>T p.Q541* | Nonsense Mutation (SNP) | VAF 17/37 reads (46%) | called by muse, mutect2, varscan2
- PRC1 | c.1470_1472dup p.T492dup | In Frame Ins (INS) | VAF 64/114 reads (56%) | called by mutect2, pindel, varscan2
- WEE1 | c.757_759del p.R254del | In Frame Del (DEL) | VAF 20/80 reads (25%) | called by pindel, varscan2
- ADAMTS15 | c.33C>T p.F11= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV54503944; called by muse, mutect2
- ARSF | c.1764G>A p.E588= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV63839854; called by muse, mutect2, varscan2
- CEP89 | c.375C>T p.D125= | Silent (SNP) | VAF 24/152 reads (16%) | catalogued as rs1050194201, COSV59864884; called by muse, mutect2, varscan2
- CHD1 | c.2080C>T p.L694= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV52341123; called by muse, mutect2, varscan2
- CUBN | c.3837G>A p.E1279= | Silent (SNP) | VAF 40/87 reads (46%) | catalogued as COSV64717720; called by muse, mutect2, varscan2
- DSCAM | c.4759C>T p.L1587= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV68020261, COSV68028306; called by muse, mutect2, varscan2
- E2F8 | c.1110G>C p.V370= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV51461502, COSV51462379; called by muse, mutect2, varscan2
- MAGI2 | c.3159G>A p.Q1053= | Silent (SNP) | VAF 88/389 reads (23%) | catalogued as rs201511382; called by muse, mutect2, varscan2
- MED12 | c.648T>G p.G216= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as COSV61331541; called by muse, mutect2, varscan2
- NBPF1 | c.1470C>T p.D490= | Silent (SNP) | VAF 60/485 reads (12%) | catalogued as COSV99844712; called by muse, mutect2, varscan2
- NEFM | c.324G>A p.L108= | Silent (SNP) | VAF 15/22 reads (68%) | catalogued as COSV55332624; called by muse, mutect2, varscan2
- PCDHB14 | c.1659C>T p.D553= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs782755321, COSV53388912; called by muse, mutect2, varscan2
- PHRF1 | c.3942G>A p.L1314= (on ENST00000264555 / NM_001286581.2; = p.L1313= on NM_020901.4) | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV52756924; called by muse, mutect2, varscan2
- PLPP4 | c.537C>G p.L179= | Silent (SNP) | VAF 21/118 reads (18%) | catalogued as COSV64828183; called by muse, mutect2, varscan2
- PTGFR | c.546G>A p.S182= | Silent (SNP) | VAF 52/121 reads (43%) | catalogued as rs765817668, COSV66115222; called by muse, mutect2, varscan2
- SLC45A1 | c.1536C>G p.L512= | Silent (SNP) | VAF 18/125 reads (14%) | catalogued as rs770426185, COSV57096177, COSV57096819; called by muse, mutect2, varscan2
- SP7 | c.744C>T p.P248= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV58191075; called by muse, mutect2, varscan2
- SRRM2 | c.150G>A p.V50= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as COSV57074370; called by muse, mutect2, varscan2
- TBC1D10B | c.1095C>T p.L365= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as rs1284825843, COSV69505161; called by muse, mutect2, varscan2
- THADA | c.1416T>C p.A472= | Silent (SNP) | VAF 52/139 reads (37%) | catalogued as COSV57685380; called by muse, mutect2, varscan2
- TNN | c.3468G>A p.A1156= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs369876797; called by muse, mutect2, varscan2
- USP19 | c.1477C>T p.L493= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV60046442; called by muse, mutect2, varscan2
- VPS35 | c.2358C>T p.S786= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as rs762118625, COSV54479190; called by muse, mutect2, varscan2
- ZNF341 | c.2118G>A p.T706= (on ENST00000375200 / NM_001282935.1; = p.T699= on NM_032819.4) | Silent (SNP) | VAF 14/134 reads (10%) | catalogued as rs141469797, COSV61010185; called by muse, mutect2
- ARIH1 | c.*3977A>T | 3'UTR (SNP) | VAF 12/31 reads (39%) | catalogued as COSV101134686; called by muse, mutect2, varscan2
- CPLANE1 | c.7813-31G>A | Intron (SNP) | VAF 24/52 reads (46%) | catalogued as COSV57062374; called by muse, mutect2, varscan2
- HMGN2P46 | n.1130T>C | RNA (SNP) | VAF 18/69 reads (26%) | called by muse, mutect2, varscan2
